Somatic mutation profile of tumor specimen MMRF_1323_1_BM_CD138pos (aliquot MMRF_1323_1_BM_CD138pos_T1_KAS5U_L01214) from MMRF case MMRF_1323, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.6 years (26,865 days).
Specimen MMRF_1323_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea4cc628-8873-426a-825d-b3194c616c1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1323_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1323_1_PB_Whole_C2_KAS5U_L01225; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5912953-61e5-4a6d-bfc6-8f207b7263f7

The open-access MAF lists 99 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 25, Intron 13, Silent 11, RNA 5, 5'UTR 5, 3'Flank 3, Splice Region 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GAT1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56997817; called by muse, varscan2
- C21orf62 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs781073580, COSV66671926; called by muse, mutect2, varscan2
- CUX1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1208666189; called by muse, mutect2
- ESRRG | c.699A>C p.P233= | Splice Region (SNP) | VAF 43/49 reads (88%) | catalogued as rs1218980842; called by muse, mutect2, varscan2
- IGHV2-70 | c.68T>G p.L23W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189702615; called by muse, varscan2
- IGKV1-5 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as rs11546105; called by muse, varscan2
- IGLL5 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as rs763474712, COSV73248991, COSV73251236, COSV73251304; called by muse, mutect2, varscan2
- KLHDC3 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 101/190 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs760348711; called by muse, mutect2, varscan2
- LIPC | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as rs759143056; called by muse, mutect2, varscan2
- LIPI | c.1340C>G p.S447* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV60710557; called by muse, mutect2
- LRCH4 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1191516384; called by muse, mutect2, varscan2
- MUC16 | c.13253C>T p.A4418V | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs952740272; called by muse, mutect2, varscan2
- OR2B6 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs372830614; called by muse, mutect2
- PPM1N | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV55594262; called by muse, mutect2, varscan2
- RGL2 | c.1054T>C p.Y352H | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV65842572; called by muse, mutect2, varscan2
- SCRIB | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as rs749547116, COSV57583952; called by muse, mutect2, varscan2
- TTN | c.74206C>T p.P24736S (on ENST00000591111; = p.P17312S on NM_003319.4) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | PolyPhen possibly damaging (0.766); catalogued as rs752752131; called by muse, mutect2
- ZC3H13 | c.3935A>C p.E1312A | Missense Mutation (SNP) | VAF 77/93 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs772254504, COSV99668685; called by muse, mutect2, varscan2
- ZNF516 | c.1079T>C p.V360A | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs909682308; called by muse, mutect2
- ABCB5 | c.3275A>G p.Q1092R (on ENST00000404938 / NM_001163941.2; = p.Q647R on NM_178559.6) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP94 | c.866A>C p.E289A (on ENST00000320267 / NM_001352064.2; = p.E295A on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CPSF1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSMD3 | c.10082G>C p.G3361A (on ENST00000297405 / NM_001363185.1; = p.G3192A on NM_052900.3) | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- DCHS1 | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FPGT-TNNI3K | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- GSTP1 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- KMT2B | c.8013C>A p.H2671Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- MYC | c.793_795del p.V265del (on ENST00000377970; = p.V280del on NM_002467.6) | In Frame Del (DEL) | VAF 56/210 reads (27%) | called by pindel, varscan2
- PCSK5 | c.3565A>T p.T1189S | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PPP2CB | c.738+1G>C p.X246_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- RIMS2 | c.4400C>A p.P1467Q (on ENST00000666250 / NM_001348490.2; = p.P1038Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL1 | c.3974T>C p.I1325T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2
- SETD2 | c.7173dup p.P2392Tfs*37 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- SLC22A2 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SP8 | c.56T>G p.L19R (on ENST00000361443 / NM_198956.4; = p.L37R on NM_182700.6) | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2
- TWIST2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZBP1 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AMZ1 | c.1279C>T p.L427= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV56687769; called by muse, mutect2, varscan2
- CALCR | c.924T>C p.S308= (on ENST00000649521 / NM_001164737.2; = p.S292= on NM_001742.4) | Silent (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- CCNB2 | c.1128C>T p.I376= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs750459393; called by mutect2, varscan2
- DCHS1 | c.5181C>T p.G1727= | Silent (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- GLRB | c.660T>C p.P220= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- GNB1L | c.871C>T p.L291= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- KIF16B | c.1569T>G p.S523= | Silent (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- MMP28 | c.1302G>A p.K434= | Silent (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- MOGAT3 | c.336C>A p.G112= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV56174728; called by muse, mutect2, varscan2
- NLGN2 | c.1344C>A p.R448= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- NUAK1 | c.219C>T p.T73= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV99776990; called by muse, mutect2, varscan2
- ABCA9 | c.2402-59A>C | Intron (SNP) | VAF 12/27 reads (44%) | called by mutect2, varscan2
- ABRA | c.-19A>G | 5'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9284G>A | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as rs782210400, COSV101595497, COSV73144969; called by muse, mutect2, varscan2
- ACER2P1 | n.767G>T | RNA (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- ASPA | c.*4143A>G | 3'UTR (SNP) | VAF 33/72 reads (46%) | catalogued as rs11551725; called by muse, mutect2, varscan2
- B3GALT5 | c.*425C>G | 3'UTR (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- BCAT1 | c.*612C>G | 3'UTR (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- BNIP1 | c.*325G>A | 3'UTR (SNP) | VAF 5/88 reads (6%) | catalogued as rs942875533, COSV51569888; called by muse, mutect2
- C2orf88 | c.*2948A>G | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- C3P1 | n.3251G>A | RNA (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- CARS2 | c.225-68A>G | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as rs1298732804; called by muse, mutect2, varscan2
- CDH7 | chr18:65883144 del A | 3'Flank (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- CDH7 | chr18:65883533 A>C | 3'Flank (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- CDKN2B | c.*198T>G | 3'UTR (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- CEP85 | c.*240G>T | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- CTSK | c.784+125T>G | Intron (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- CXCR5 | c.51+2850A>G | Intron (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- DNM3 | c.1911+1270G>A | Intron (SNP) | VAF 6/98 reads (6%) | catalogued as rs1218506898; called by muse, mutect2
- DSC1 | c.*581G>A | 3'UTR (SNP) | VAF 3/33 reads (9%) | catalogued as rs1017709833; called by muse, mutect2
- EBF3 | chr10:129836235 A>T | 3'Flank (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- ERF | c.258-52A>G | Intron (SNP) | VAF 16/46 reads (35%) | catalogued as rs750915227; called by muse, mutect2
- EVI2A | c.*720_*723del | 3'UTR (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- GLB1L3 | c.-316C>T | 5'UTR (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- GPR158 | c.*108A>G | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- HCAR3 | c.*701A>G | 3'UTR (SNP) | VAF 8/217 reads (4%) | called by muse, mutect2
- HIPK1 | c.*2014del | 3'UTR (DEL) | VAF 10/23 reads (43%) | catalogued as rs879095098; called by mutect2, varscan2
- LTB | c.209-53G>A | Intron (SNP) | VAF 49/91 reads (54%) | catalogued as rs561587978; called by muse, mutect2, varscan2
- LTB | c.208+28G>A | Intron (SNP) | VAF 86/159 reads (54%) | catalogued as rs749649327, COSV59864452; called by muse, mutect2, varscan2
- MAG | c.-102G>A | 5'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- MIR543 | n.56C>T | RNA (SNP) | VAF 25/49 reads (51%) | catalogued as rs760890689; called by muse, mutect2, varscan2
- MUS81 | c.1059+82G>C | Intron (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- NECAB1 | c.*1744del | 3'UTR (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- OR2L1P | n.681T>C | RNA (SNP) | VAF 13/264 reads (5%) | called by muse, mutect2
- PDS5A | c.138+124T>A | Intron (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*5591C>A | 3'UTR (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- POU2F1 | c.*3188A>G | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- RNPS1 | c.*43C>T | 3'UTR (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- RPH3AL | c.-1C>T | 5'UTR (SNP) | VAF 38/105 reads (36%) | catalogued as rs1216660570; called by muse, mutect2, varscan2
- SNORD114-7 | n.68T>G | RNA (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- SNX1 | c.*1352A>G | 3'UTR (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- SP1 | c.*5105G>A | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- SYNPO2 | c.*2055G>A | 3'UTR (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- TAPT1 | c.*278C>T | 3'UTR (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- TBL2 | c.130+150C>T | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- TBXAS1 | c.333+2231A>G | Intron (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- TMC1 | c.*150G>T | 3'UTR (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- TMEM129 | c.-108G>C | 5'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, varscan2
- TRPV4 | c.*397C>T | 3'UTR (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- UNC5A | c.*927T>C | 3'UTR (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- WNT16 | c.*876C>T | 3'UTR (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- ZNF716 | c.*1767del | 3'UTR (DEL) | VAF 23/65 reads (35%) | catalogued as rs560372164; called by mutect2, pindel, varscan2
